CCDI case PBCRFD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f6fff4ca-efd4-4a34-9293-c0a1a0205106

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Atypical meningioma: ICD-O-3 morphology code: 9539/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.4 years (4,906 days).

Biospecimens (3 samples)
- Sample 0DXMLI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXMNM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DXVLB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
